Somatic mutation profile of tumor specimen TCGA-CW-5588-01A (aliquot TCGA-CW-5588-01A-01D-1534-10) from TCGA case TCGA-CW-5588, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 78.6 years (28,714 days).
Specimen TCGA-CW-5588-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7cb27cb-42d0-43cf-ab0e-65b55808f561.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5588-11A (Solid Tissue Normal), aliquot TCGA-CW-5588-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77c54516-376d-4b21-bb6a-deedbb2b727f

The open-access MAF lists 58 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, Nonsense Mutation 3, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 45/129 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs397516444, CM951291, CM951292, COSV56546524, COSV56553028, COSV56557871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRE5 | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV54408872, COSV54411716; called by muse, varscan2
- ARHGAP36 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1460939004, COSV52263824; called by muse, mutect2, varscan2
- BHMT | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57154581; called by muse, mutect2, varscan2
- BLM | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV61924587; called by muse, mutect2, varscan2
- C14orf39 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV58782462; called by muse, mutect2
- CEP70 | c.1720C>T p.L574F | Missense Mutation (SNP) | VAF 143/608 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53875989; called by muse, mutect2, varscan2
- COL1A2 | c.3331G>T p.G1111C | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51959264; called by muse, mutect2
- CYP4B1 | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs373978131; called by muse, mutect2, varscan2
- DDX17 | c.1385A>G p.N462S | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV53253062; called by muse, mutect2, varscan2
- DENND10 | c.287A>C p.D96A | Missense Mutation (SNP) | VAF 226/877 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63857733; called by muse, mutect2, varscan2
- EIF4G3 | c.3758G>T p.G1253V | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV51683766; called by muse, mutect2, varscan2
- ESPL1 | c.6361T>C p.*2121Qext*13 | Nonstop Mutation (SNP) | VAF 14/208 reads (7%) | catalogued as COSV54476375; called by muse, mutect2
- FAM193A | c.3722C>T p.A1241V (on ENST00000324666 / NM_001256666.1; = p.A1200V on NM_003704.3) | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV61194768; called by muse, mutect2, varscan2
- FLAD1 | c.71T>A p.L24* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV52697353; called by muse, mutect2, varscan2
- GLP1R | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64715275; called by muse, mutect2, varscan2
- GPR37L1 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66162382; called by muse, mutect2, varscan2
- IGHG2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs587630560; called by muse, varscan2
- IGHV1OR21-1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs1418373541; called by muse, mutect2
- ITPR1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.487); catalogued as COSV56984697; called by muse, mutect2, varscan2
- LONRF1 | c.1760T>G p.F587C | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68036971; called by muse, mutect2, varscan2
- MED26 | c.1246A>C p.K416Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV54660624; called by muse, mutect2
- NOCT | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54936208; called by muse, mutect2, varscan2
- NOP56 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61390264; called by muse, mutect2, varscan2
- OR2T12 | c.491T>C p.F164S | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750957819, COSV58777790; called by muse, mutect2, varscan2
- PKHD1L1 | c.3878G>C p.R1293T | Missense Mutation (SNP) | VAF 22/419 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV65744442; called by muse, mutect2
- PRDM10 | c.1846T>C p.F616L | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58801679; called by muse, mutect2, varscan2
- RIOK1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV53572165; called by muse, mutect2, varscan2
- SCGN | c.433A>C p.I145L | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as COSV58545824; called by muse, mutect2, varscan2
- SLC39A12 | c.1171C>A p.H391N | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66198870; called by muse, mutect2, varscan2
- STAB2 | c.2157C>A p.C719* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV66340194; called by muse, mutect2, varscan2
- TMTC1 | c.1619C>A p.A540D (on ENST00000539277 / NM_001193451.2; = p.A432D on NM_175861.3) | Missense Mutation (SNP) | VAF 70/781 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55483520, COSV55487361; called by muse, mutect2
- TMTC2 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 68/801 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1036204821, COSV58270840; called by muse, mutect2
- TTBK2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 60/459 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV51162989; called by muse, mutect2, varscan2
- USP49 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs751837819, COSV51895413; called by muse, mutect2
- XIRP2 | c.5483A>T p.K1828I (on ENST00000628543; = p.K2003I on NM_152381.6) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV54704977; called by muse, mutect2, varscan2
- YES1 | c.815T>G p.I272S | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV58850568; called by muse, mutect2, varscan2
- ZFYVE26 | c.4276T>A p.W1426R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61329279; called by muse, mutect2, varscan2
- ZFYVE26 | c.4275T>A p.D1425E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV61329290; called by muse, mutect2, varscan2
- ZGRF1 | c.5507A>T p.D1836V | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101500584, COSV71393223; called by muse, varscan2
- ZMYM2 | c.3832A>G p.T1278A | Missense Mutation (SNP) | VAF 91/334 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.184); catalogued as rs1302200921, COSV67034657; called by muse, mutect2, varscan2
- ZNF665 | c.1196G>A p.G399D (on ENST00000600412; = p.G464D on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV67215512; called by muse, mutect2, varscan2
- ZSCAN9 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs941676970, COSV52849899, COSV52851227; called by muse, mutect2, varscan2
- ASXL2 | c.122_124del p.E41del | In Frame Del (DEL) | VAF 63/261 reads (24%) | called by mutect2, varscan2
- GALNT7 | c.27_28insAA p.R10Nfs*13 | Frame Shift Ins (INS) | VAF 47/192 reads (24%) | called by mutect2, varscan2
- H2BC14 | c.154del p.D52Tfs*12 | Frame Shift Del (DEL) | VAF 32/143 reads (22%) | called by mutect2, varscan2
- OTUD6A | c.614T>A p.I205N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- ADAR | c.2241C>T p.V747= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs780746416, COSV52715843; called by muse, mutect2, varscan2
- C12orf40 | c.1053A>T p.T351= | Silent (SNP) | VAF 47/236 reads (20%) | catalogued as COSV61133171; called by muse, mutect2, varscan2
- DHX29 | c.1458A>G p.K486= | Silent (SNP) | VAF 134/1241 reads (11%) | catalogued as COSV52418764; called by muse, mutect2, varscan2
- FAM193B | c.1872G>A p.L624= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1309709664, COSV61557917; called by muse, mutect2, varscan2
- HECW2 | c.522T>A p.G174= | Silent (SNP) | VAF 75/276 reads (27%) | catalogued as COSV53661597, COSV53676008; called by muse, mutect2, varscan2
- MAS1L | c.1062A>T p.P354= | Silent (SNP) | VAF 107/343 reads (31%) | catalogued as COSV65809036; called by muse, mutect2, varscan2
- MYO16 | c.1410T>C p.P470= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV51798077; called by muse, mutect2, varscan2
- PDZD8 | c.1551A>G p.S517= | Silent (SNP) | VAF 70/466 reads (15%) | catalogued as rs778850329, COSV57825937; called by muse, mutect2, varscan2
- RIMS3 | c.870C>A p.L290= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV65504685; called by muse, mutect2, varscan2
- SETX | c.5758C>T p.L1920= | Silent (SNP) | VAF 72/232 reads (31%) | catalogued as COSV56386900; called by muse, mutect2, varscan2
- OR5AU1 | c.-65G>A | 5'UTR (SNP) | VAF 55/176 reads (31%) | catalogued as COSV58615674; called by muse, mutect2, varscan2
